Somatic mutation profile of tumor specimen C3L-07672-03 (aliquot CPT0479410010) from CPTAC case C3L-07672, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.3 years (28,587 days).
Specimen C3L-07672-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 362b00be-72a3-4ee9-ba3c-933169c945bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07672-31 (Blood Derived Normal), aliquot CPT0479540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/832ebeb8-b50d-4972-819a-fc6d3d89abbf

The open-access MAF lists 1,381 somatic variants for this specimen: 903 protein-altering or splice-affecting, 426 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 831, Silent 426, Nonsense Mutation 58, Intron 28, Splice Region 10, 5'Flank 8, 3'UTR 7, 5'UTR 4, RNA 3, 3'Flank 2, In Frame Del 2, Splice Site 1.

Variants (750 of 1,381; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.7324C>T p.R2442* | Nonsense Mutation (SNP) | VAF 40/456 reads (9%) | catalogued as rs769364943, COSV54125310; ClinVar: pathogenic; called by muse, mutect2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KMT2A | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as rs1555035511, COSV63292737; ClinVar: pathogenic; called by muse, mutect2
- MYO18B | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 26/344 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.67); PolyPhen benign (0.344); catalogued as COSV100123667, COSV59127388; called by muse, mutect2
- NEXMIF | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 29/222 reads (13%) | catalogued as rs1556016731, CM156012, COSV50023631; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555634422, CM032632; ClinVar: likely pathogenic; called by muse, mutect2
- SGSH | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 70/461 reads (15%) | catalogued as rs374621913, CM002395; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 24/291 reads (8%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2
- A1CF | c.1328G>A p.G443E (on ENST00000373993 / NM_138932.2; = p.G435E on NM_014576.4) | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as COSV51021240; called by muse, mutect2
- ABCB1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55955044; called by muse, mutect2
- ACADL | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99284590; called by muse, mutect2
- ACE | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs897870088; called by muse, mutect2
- ACSS3 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698097; called by muse, mutect2
- ADAM18 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV55844402; called by muse, mutect2
- ADAMTSL1 | c.4375C>T p.L1459F | Missense Mutation (SNP) | VAF 30/389 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.403); catalogued as rs1232464574; called by muse, mutect2
- ADD2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV52471252; called by muse, mutect2
- ADGRL4 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.533); catalogued as COSV100875654; called by muse, mutect2
- ADH1A | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52924612; called by muse, mutect2
- ADNP2 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs371223824; called by muse, mutect2
- ADTRP | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1468624213; called by muse, mutect2
- AGBL1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1328591315, COSV66864526; called by muse, mutect2
- AKR1B15 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 56/508 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.537); catalogued as rs764458887; called by muse, mutect2, varscan2
- ALDH16A1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs764220407; called by muse, mutect2, varscan2
- ALDH18A1 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 20/346 reads (6%) | catalogued as rs887933055, COSV64662685; called by muse, mutect2
- ALOX12B | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1393418105, COSV59876314; called by muse, mutect2, varscan2
- ANK3 | c.8809G>A p.E2937K | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV55066722; called by muse, mutect2
- AP1G1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | catalogued as rs868015561, COSV55485025; called by muse, mutect2
- AP5Z1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs370516405; called by muse, mutect2, varscan2
- APOB | c.10337G>A p.G3446E | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51931934; called by muse, mutect2
- ARHGAP15 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs759344166, COSV54509110, COSV54514150; called by muse, mutect2
- ARHGAP28 | c.2140C>T p.R714C (on ENST00000383472 / NM_001366230.1; = p.R555C on NM_001010000.3) | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV58655431; called by muse, mutect2, varscan2
- ARHGEF28 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as COSV99709384; called by muse, mutect2
- ARID1A | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs984459719, COSV61372766; called by muse, mutect2, varscan2
- ARRDC2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.137); catalogued as rs1244299459, COSV55846075; called by muse, mutect2
- ASAP2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV99855757; called by muse, mutect2
- ASAP2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99857063; called by muse, mutect2
- ASTN1 | c.3574C>T p.L1192F | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as COSV62492158, COSV62502715; called by muse, mutect2, varscan2
- ASTN2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); catalogued as rs752923196, COSV57779503; called by muse, mutect2, varscan2
- ASXL3 | c.4109C>T p.P1370L | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV99327088; called by muse, mutect2
- ATCAY | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV56654775; called by muse, mutect2
- ATP2A1 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as CD137932; called by muse, mutect2
- ATRNL1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs368755603, COSV100746539; called by muse, mutect2
- BARX2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 33/340 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs376626609; called by muse, mutect2
- BFAR | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.624); catalogued as rs763197755; called by muse, mutect2
- BICRAL | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV58408055; called by muse, mutect2
- BMP5 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1287843451; called by muse, mutect2
- BOLL | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377264153; called by muse, mutect2, varscan2
- BPNT1 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 57/379 reads (15%) | catalogued as COSV59040313; called by muse, mutect2, varscan2
- BRINP1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 30/277 reads (11%) | catalogued as COSV56297934; called by muse, varscan2
- BRINP2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1418455034, COSV64177622; called by muse, mutect2
- C10orf71 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 31/480 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762918373, COSV60504482; called by muse, mutect2
- C2orf78 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV68517636; called by muse, mutect2
- C5orf46 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1168566782, COSV100568401; called by muse, mutect2, varscan2
- C6 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV99667135; called by muse, mutect2
- C6orf132 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 51/609 reads (8%) | SIFT deleterious (0); catalogued as rs747876608; called by muse, mutect2
- C6orf141 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs945681656; called by muse, mutect2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2
- C8B | c.1644G>A p.W548* | Nonsense Mutation (SNP) | VAF 32/351 reads (9%) | catalogued as COSV64778163; called by muse, mutect2
- CAB39L | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 18/320 reads (6%) | catalogued as COSV61717093; called by muse, mutect2
- CACNA2D3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV55565970; called by muse, mutect2
- CALHM6 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs891470152; called by muse, mutect2
- CAMKV | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56554015; called by muse, mutect2, varscan2
- CAPN11 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV67236260; called by muse, mutect2
- CAPN13 | c.198G>A p.Q66= | Splice Region (SNP) | VAF 13/189 reads (7%) | catalogued as rs1222793339; called by muse, mutect2
- CASD1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs758075203; called by muse, mutect2
- CASQ2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs781262104; called by muse, mutect2, varscan2
- CASZ1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs998228802, COSV59738021; called by muse, mutect2, varscan2
- CATSPERB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56421924; called by muse, mutect2
- CBFA2T2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1050504741, COSV60074811; called by muse, mutect2
- CCDC66 | c.1237G>A p.G413R (on ENST00000394672 / NM_001353147.1; = p.G379R on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as rs746252416; called by muse, mutect2
- CCDC69 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs771086853; called by muse, mutect2, varscan2
- CCDC70 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1420323317, COSV54431119; called by muse, mutect2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2
- CD177 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs868371538, COSV65122460; called by muse, mutect2
- CDHR4 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273698633; called by muse, mutect2
- CDK12 | c.3937C>T p.P1313S (on ENST00000447079 / NM_016507.4; = p.P1304S on NM_015083.3) | Missense Mutation (SNP) | VAF 64/406 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV71002735; called by muse, mutect2, varscan2
- CDKN1A | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 31/492 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1379336902, COSV55191443; called by muse, mutect2
- CELSR1 | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 16/235 reads (7%) | catalogued as rs1395192638, COSV53084327; called by muse, mutect2
- CEP192 | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1025521676; called by muse, mutect2, varscan2
- CFAP74 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54567255; called by muse, mutect2, varscan2
- CHI3L1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99703722; called by muse, mutect2, varscan2
- CHP2 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs1167190804, COSV100270079; called by muse, mutect2
- CHRNB2 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs1462453336; called by muse, mutect2
- CHST5 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 42/395 reads (11%) | catalogued as COSV60339965; called by muse, mutect2, varscan2
- CIITA | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV60854584; called by muse, mutect2
- CLASP1 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1289906670; called by muse, mutect2
- CLEC14A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 41/514 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV60561956; called by muse, mutect2
- CLEC18C | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as rs781213512; called by muse, mutect2
- CLEC2L | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs867820949; called by muse, mutect2, varscan2
- CLEC6A | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV101165699, COSV65987765; called by muse, mutect2
- CLVS2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51559280; called by muse, mutect2
- CMYA5 | c.7630C>T p.Q2544* | Nonsense Mutation (SNP) | VAF 30/346 reads (9%) | catalogued as COSV71405291; called by muse, mutect2
- CNN3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs891411357, COSV64637535; called by muse, mutect2
- CNR1 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62986328; called by muse, mutect2
- CNTNAP4 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV56662156; called by muse, mutect2
- CNTNAP4 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs767695441; called by muse, mutect2
- COBLL1 | c.959C>T p.S320F (on ENST00000392717; = p.S282F on NM_014900.5) | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99527495; called by muse, mutect2
- COL21A1 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs867236544; called by muse, mutect2, varscan2
- COL21A1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777256; called by muse, mutect2
- COL4A2 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 39/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178438876; called by muse, mutect2, varscan2
- COL4A5 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM115527, CM995169; called by muse, varscan2
- COL6A5 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.705); catalogued as COSV55217538; called by muse, mutect2
- CORIN | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV56699006; called by muse, mutect2
- CPED1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778673545; called by muse, mutect2, varscan2
- CPZ | c.968G>A p.R323Q (on ENST00000360986 / NM_001014447.3; = p.R312Q on NM_003652.3) | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs538634471, COSV59921979; called by muse, mutect2
- CR1 | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.122); catalogued as COSV65464306; called by muse, mutect2
- CRB1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.269); catalogued as COSV66343060; called by muse, mutect2
- CRISP3 | c.551G>A p.G184E (on ENST00000371159 / NM_001368123.1; = p.G166E on NM_006061.4) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53820675; called by muse, mutect2
- CRISP3 | c.550G>A p.G184R (on ENST00000371159 / NM_001368123.1; = p.G166R on NM_006061.4) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53820981; called by muse, mutect2
- CRISP3 | c.214G>A p.E72K (on ENST00000371159 / NM_001368123.1; = p.E54K on NM_006061.4) | Missense Mutation (SNP) | VAF 27/417 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as rs866284987, COSV99539026; called by muse, mutect2
- CRYGB | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV53680240; called by muse, mutect2
- CSF1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 50/396 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as COSV60033136; called by muse, mutect2, varscan2
- CSMD2 | c.6481C>T p.L2161F | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912663123; called by muse, mutect2, varscan2
- CTCFL | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 37/438 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs899433950, COSV54773956; called by muse, mutect2
- CUZD1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868328670, COSV59025861; called by muse, mutect2
- CYLC1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV61413987; called by muse, mutect2, varscan2
- CYP2F1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 26/365 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV58526711; called by muse, mutect2
- CYP4F22 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV99513012; called by muse, mutect2
- DAB1 | c.1618G>A p.D540N (on ENST00000371231; = p.D507N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.917); catalogued as COSV64690058, COSV64690164; called by muse, mutect2
- DBX2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV60339138; called by muse, mutect2
- DCDC1 | c.2265G>A p.W755* | Nonsense Mutation (SNP) | VAF 21/316 reads (7%) | catalogued as COSV100663142; called by muse, mutect2
- DDR2 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63370753; called by muse, mutect2
- DDX31 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.364); catalogued as rs866139523, COSV60135982; called by muse, mutect2
- DEFB125 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1568457505, COSV66703046; called by muse, mutect2
- DEFB129 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs962238617; called by muse, mutect2
- DHRS2 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1332719061; called by muse, mutect2
- DHX35 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52669156; called by muse, mutect2
- DMBT1 | c.3155C>T p.S1052L (on ENST00000338354 / NM_001377530.1; = p.S553L on NM_004406.3) | Missense Mutation (SNP) | VAF 34/543 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs759248480; called by muse, mutect2
- DNAAF4 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs955624614; called by muse, mutect2
- DNAH1 | c.12568G>A p.E4190K | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs200056328; called by muse, mutect2
- DNAH11 | c.7063C>T p.P2355S | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs772253654; called by muse, mutect2, varscan2
- DNAH3 | c.4504C>T p.Q1502* | Nonsense Mutation (SNP) | VAF 24/360 reads (7%) | catalogued as rs1381020504; called by muse, mutect2
- DNAH5 | c.8881G>A p.G2961R | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54203613; called by muse, mutect2
- DNAH5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99455298; called by muse, mutect2
- DNAH6 | c.10778G>A p.G3593E | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866325994; called by muse, mutect2
- DNAH7 | c.8666G>A p.R2889Q | Missense Mutation (SNP) | VAF 37/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752692000, COSV56784652; called by muse, mutect2
- DNAH8 | c.9259G>A p.D3087N | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV59477220; called by muse, mutect2
- DNAH8 | c.12676G>A p.E4226K | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV100544295; called by muse, mutect2
- DNAJB13 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.443); catalogued as rs201648384; called by muse, mutect2
- DOCK9 | c.5240G>A p.R1747Q (on ENST00000376460 / NM_001366676.2; = p.R1748Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as rs559984159, COSV59631183; called by muse, mutect2, varscan2
- DOP1B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as COSV67694789; called by muse, mutect2
- DPP6 | c.430C>T p.H144Y (on ENST00000377770 / NM_001364500.2; = p.H82Y on NM_001936.5) | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100122859, COSV59600961; called by muse, mutect2, varscan2
- DPP6 | c.511G>A p.E171K (on ENST00000377770 / NM_001364500.2; = p.E109K on NM_001936.5) | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.46); catalogued as rs1461095353, COSV59596064; called by muse, mutect2
- DPP6 | c.577G>A p.E193K (on ENST00000377770 / NM_001364500.2; = p.E131K on NM_001936.5) | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs186683462, COSV59623612; called by muse, mutect2
- DRC1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as COSV55506603; called by muse, mutect2
- DSG3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128517; called by muse, mutect2
- DSPP | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 33/493 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV56808438; called by muse, mutect2
- ECD | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs746823344; called by muse, mutect2
- EEF1A2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 39/502 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV53205688; called by muse, mutect2
- ELK4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 43/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466421386; called by muse, mutect2
- EPHB2 | c.1703G>A p.R568Q (on ENST00000400191 / NM_001309193.2; = p.R569Q on NM_004442.7) | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1248584369; called by muse, mutect2
- EYA1 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV100378524; called by muse, mutect2
- EYS | c.3808G>A p.V1270I | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1284747107, COSV58196200; called by muse, mutect2
- F13B | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV66372835; called by muse, mutect2, varscan2
- FAM186A | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 43/472 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs959523367; called by muse, mutect2
- FAM47C | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as rs1261108012; called by muse, mutect2, varscan2
- FAT3 | c.7963C>T p.P2655S | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV53092684; called by muse, mutect2
- FAT4 | c.3755G>A p.G1252E | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1225418855, COSV67880624; called by muse, mutect2
- FAT4 | c.10924G>A p.D3642N | Missense Mutation (SNP) | VAF 22/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58683502; called by muse, mutect2
- FBXO8 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67031546; called by muse, mutect2
- FBXO8 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101183683; called by muse, mutect2
- FER1L5 | c.880G>A p.D294N (on ENST00000623019; = p.D311N on NM_001293083.2) | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1369047771; called by muse, mutect2
- FGF14 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865878627, COSV101084423, COSV65941304; called by muse, mutect2, varscan2
- FNDC1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV51949753; called by muse, mutect2
- FOXE1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 38/533 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1202969544; called by muse, mutect2
- FRAS1 | c.8752G>A p.V2918M | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53586172; called by muse, mutect2
- FRAS1 | c.9893G>A p.G3298E | Missense Mutation (SNP) | VAF 15/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560419713; called by muse, mutect2
- FRAS1 | c.10500G>A p.M3500I | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs914272465; called by muse, mutect2
- FRMPD3 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1193246029; called by muse, mutect2, varscan2
- FRY | c.8246C>T p.S2749F | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1336841249; called by muse, mutect2
- FUT5 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1263448580; called by muse, varscan2
- FYB2 | c.674G>A p.W225* | Nonsense Mutation (SNP) | VAF 36/330 reads (11%) | catalogued as rs756823431, COSV58586739, COSV58588861; called by muse, mutect2, varscan2
- GHR | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180863009; called by muse, mutect2, varscan2
- GIPR | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99625117; called by muse, mutect2
- GPR149 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs1397569038; called by muse, mutect2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2
- GPR50 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768602851, COSV54437313; called by muse, mutect2, varscan2
- GRIA1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV53600207, COSV53616041; called by muse, mutect2
- GRIK2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1312199028, COSV59737564; called by muse, mutect2, varscan2
- GRIN2A | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1325032512; called by muse, mutect2
- GRIN2A | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV58029287; called by muse, mutect2
- GRIN3A | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 37/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868638738, COSV62451702; called by muse, mutect2
- GRIP2 | c.619G>A p.D207N (on ENST00000619221; = p.D110N on NM_001080423.4) | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs759832768, COSV56119540; called by muse, mutect2
- GUCY1A2 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV56479667; called by muse, mutect2
- HAUS8 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs571234172; called by muse, mutect2
- HCFC1 | c.5593C>T p.R1865C | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60072013; called by muse, mutect2, varscan2
- HDC | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs377513123, COSV99984380; called by muse, mutect2, varscan2
- HECTD4 | c.6760C>T p.L2254F | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs755587067; called by muse, mutect2
- HECW1 | c.2128G>A p.G710S | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV67838509; called by muse, mutect2, varscan2
- HHIPL2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as COSV58563783; called by muse, mutect2, varscan2
- HLA-DRA | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV66622558; called by muse, mutect2
- HNF4G | c.231G>A p.M77I (on ENST00000354370 / NM_001330561.2; = p.M124I on NM_004133.5) | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs867924573, COSV100584026; called by muse, mutect2, varscan2
- HNF4G | c.593G>A p.G198E (on ENST00000354370 / NM_001330561.2; = p.G245E on NM_004133.5) | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62965564; called by muse, mutect2
- HNRNPA0 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 119/418 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1325932507; called by muse, mutect2, varscan2
- HYDIN | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55477484; called by muse, mutect2
- IKZF1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100498738; called by muse, mutect2, varscan2
- IL17RA | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 37/479 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456279112; called by muse, mutect2
- IQUB | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV61238325; called by muse, mutect2, varscan2
- ISLR | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 35/381 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752028708, COSV51433885; called by muse, mutect2
- ITGAM | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99791859; called by muse, mutect2
- ITGB5 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56149099; called by muse, mutect2, varscan2
- JCAD | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs1337811867, COSV64759662; called by muse, mutect2
- KANK2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.127); catalogued as rs754363529; called by muse, mutect2, varscan2
- KCNK10 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1388738317, COSV100068090; called by muse, mutect2, varscan2
- KCNQ1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 58/613 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781333509; called by muse, mutect2
- KCNQ4 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV61272519; called by muse, mutect2
- KDM3B | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 117/441 reads (27%) | catalogued as COSV100070378; called by muse, mutect2, varscan2
- KIAA1217 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64610430; called by muse, mutect2
- KIAA1217 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100287190; called by muse, mutect2
- KIAA1217 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); catalogued as rs1272657340, COSV56813851; called by muse, mutect2
- KLHL24 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763228635, COSV54424734; called by muse, mutect2, varscan2
- KLK11 | c.476G>A p.R159Q (on ENST00000594768 / NM_144947.3; = p.R127Q on NM_006853.3) | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs776611966; called by muse, mutect2
- KMT2B | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 22/498 reads (4%) | catalogued as COSV55857965; called by muse, mutect2
- KRTAP13-4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866802212; called by muse, mutect2, varscan2
- KRTAP13-4 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.376); catalogued as rs779170415, COSV61879133; called by muse, mutect2
- KRTAP2-3 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 29/556 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as rs1328069269; called by muse, mutect2
- KY | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as COSV71016738; called by muse, mutect2, varscan2
- LAD1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs1280390171, COSV66213102; called by muse, mutect2, varscan2
- LCN2 | c.276G>A p.R92= | Splice Region (SNP) | VAF 26/336 reads (8%) | catalogued as COSV52979390; called by muse, mutect2
- LHCGR | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.649); catalogued as COSV54296203; called by muse, mutect2
- LILRA2 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV52189088, COSV52191649; called by muse, mutect2
- LNX1 | c.1262G>A p.G421D (on ENST00000263925 / NM_001126328.3; = p.G325D on NM_032622.2) | Missense Mutation (SNP) | VAF 42/511 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426099129; called by muse, mutect2
- LOXHD1 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as rs1232246613; called by muse, mutect2
- LRP1B | c.12596G>A p.G4199E | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs868543953, COSV67186838; called by muse, mutect2
- LTBP1 | c.3335C>T p.S1112L (on ENST00000404816 / NM_206943.4; = p.S786L on NM_000627.4) | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1440930682, COSV55380845; called by muse, mutect2
- MAP7 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 33/403 reads (8%) | catalogued as rs1474005117, COSV100643916; called by muse, mutect2
- MEF2C | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV60926568; called by muse, mutect2
- MERTK | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as rs369655379; called by muse, mutect2, varscan2
- MGAM | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 68/500 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV72073666; called by muse, varscan2
- MGAM | c.4519G>A p.V1507I | Missense Mutation (SNP) | VAF 72/458 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as rs527929510, COSV72075420, COSV72075783; called by muse, mutect2, varscan2
- MLF1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV63034754; called by muse, mutect2
- MLXIPL | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs782705841; called by muse, mutect2, varscan2
- MMP2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as rs773564814, COSV54600773; called by muse, mutect2
- MROH5 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV61472713; called by muse, mutect2
- MSR1 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747444467; called by muse, mutect2
- MUC16 | c.33652G>A p.E11218K | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV67486333; called by muse, mutect2
- MUC16 | c.25657C>T p.P8553S | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV67493952; called by muse, mutect2
- MUC16 | c.24283G>A p.D8095N | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV101200641; called by muse, mutect2
- MUC16 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV67453163; called by muse, mutect2
- MUC17 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs755642154; called by muse, mutect2, varscan2
- MUC3A | c.7640C>T p.T2547I | Missense Mutation (SNP) | VAF 28/525 reads (5%) | SIFT tolerated, low confidence (0.12); catalogued as rs374517359; called by muse, mutect2
- MYCT1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 27/401 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65891728; called by muse, mutect2
- MYH7 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as CM118273; called by muse, mutect2
- MYH7 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62519357; called by muse, mutect2
- MYLK3 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs146348278; called by muse, mutect2
- MYO18B | c.6896G>A p.G2299E | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV59132022; called by muse, mutect2
- MYOCD | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV58513130; called by muse, mutect2
- MYT1L | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as COSV67708295; called by muse, mutect2
- NAB2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV55667244; called by muse, mutect2
- NAP1L2 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV65172314; called by muse, mutect2
- NBR1 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs916966617; called by muse, mutect2, varscan2
- NDNF | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as COSV65632391; called by muse, mutect2
- NEB | c.19801G>A p.V6601I | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs1434539229; called by muse, mutect2
- NEB | c.15201G>A p.M5067I | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV51417752; called by muse, mutect2
- NEBL | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as COSV65803817; called by muse, mutect2
- NFE2L1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs767422993; called by muse, mutect2, varscan2
- NHLRC2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 18/335 reads (5%) | catalogued as rs1362621778, COSV65174582; called by muse, mutect2
- NLRP13 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.63); catalogued as rs571828268, COSV100738074, COSV61622951, COSV61623773; called by muse, mutect2
- NOL4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs757148536, COSV52338009; called by muse, mutect2
- NOS1 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57619561; called by muse, mutect2
- NPIPA5 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.65); catalogued as rs775623151; called by muse, mutect2
- NPR1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1388685174, COSV100903710; called by muse, mutect2
- NPTX2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1031855244, COSV55717193; called by muse, mutect2, varscan2
- NRAP | c.1885C>T p.H629Y (on ENST00000359988 / NM_001322945.2; = p.H594Y on NM_006175.4) | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63493557; called by muse, mutect2
- NRG3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 25/403 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100932801, COSV64574651; called by muse, mutect2
- NRSN1 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65893694; called by muse, mutect2
- NRXN1 | c.3779G>A p.G1260D | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV60491049; called by muse, mutect2
- NUDT17 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1311174553, COSV100566824; called by muse, mutect2
- NUP210L | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 28/401 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV55146489, COSV55147569; called by muse, mutect2
- NYAP1 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 71/512 reads (14%) | catalogued as COSV55716957; called by muse, mutect2, varscan2
- NYNRIN | c.4273C>T p.P1425S | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV101230721; called by muse, mutect2
- OLFM3 | c.1197G>A p.M399I (on ENST00000338858 / NM_001288821.1; = p.M379I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.932); catalogued as COSV58796593; called by muse, mutect2
- OR10A2 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV104407487, COSV56299260; called by muse, mutect2
- OR10H5 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58277802; called by muse, mutect2
- OR12D2 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 46/716 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); catalogued as rs765252057, COSV65829856; called by muse, mutect2
- OR4A47 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs267602922, COSV71444847; called by muse, mutect2, varscan2
- OR4C13 | c.73A>T p.I25L | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); catalogued as COSV73648934; called by muse, mutect2
- OR4C15 | c.217C>T p.P73S (on ENST00000314644; = p.P19S on NM_001001920.2) | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV58954091, COSV58955509; called by muse, mutect2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2
- OR4K1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53458821; called by muse, mutect2
- OR51L1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV58625417; called by muse, mutect2
- OR52L1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV59989072; called by muse, mutect2
- OR52L1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100176090; called by muse, mutect2
- OR52R1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61888571; called by muse, mutect2
- OR5P3 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV60429416; called by muse, mutect2
- OR6K3 | c.413G>A p.R138K (on ENST00000368146; = p.R122K on NM_001005327.2) | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs267598106; called by muse, mutect2, varscan2
- OR7G3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV59641039; called by muse, mutect2
- OR8B12 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 41/480 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as rs771625322, COSV60912553; called by muse, mutect2
- OTOGL | c.6355C>T p.Q2119* (on ENST00000547103; = p.Q2110* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/191 reads (5%) | catalogued as rs1343148883, CM1513068; called by muse, mutect2
- PARPBP | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.319); catalogued as COSV100569308; called by muse, mutect2
- PCDH15 | c.5243C>T p.P1748L | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1449720174; called by muse, mutect2
- PCDHA2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as rs539789047, COSV65365074; called by muse, mutect2, varscan2
- PCDHA3 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV100793134; called by muse, mutect2, varscan2
- PCDHB6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as rs1251423870, COSV50709064; called by muse, mutect2, varscan2
- PCDHGA7 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.219); catalogued as COSV53988463; called by muse, mutect2
- PCLO | c.11071G>A p.E3691K | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs900975185, COSV61622367; called by muse, mutect2, varscan2
- PCLO | c.4558G>A p.E1520K | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as COSV61667817; called by muse, mutect2
- PCNX2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs919307640; called by muse, mutect2
- PCSK1 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226940; called by muse, mutect2
- PCSK2 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV52740210; called by muse, mutect2, varscan2
- PDE1B | c.411G>A p.R137= | Splice Region (SNP) | VAF 21/269 reads (8%) | catalogued as COSV54496518; called by muse, mutect2
- PDHA2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 32/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192544011, COSV54778931; called by muse, mutect2
- PDHA2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.619); catalogued as rs865933539, COSV54779463; called by muse, mutect2
- PDZRN4 | c.2473G>A p.E825K (on ENST00000402685 / NM_001164595.2; = p.E567K on NM_013377.4) | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.225); catalogued as rs760195541, COSV54204948, COSV54207540; called by muse, mutect2
- PGK2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV59162902; called by muse, mutect2
- PHKA1 | c.2912G>A p.R971Q | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs782702439; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHLDB2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs773194445; called by muse, mutect2
- PIEZO2 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100128757; called by muse, mutect2, varscan2
- PKHD1L1 | c.4546G>A p.E1516K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV65740830; called by muse, mutect2
- PKHD1L1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV65736872, COSV65743471; called by muse, mutect2
- PLB1 | c.3250A>G p.T1084A | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs765942077; called by muse, mutect2
- PLCB1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 37/470 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV62067951, COSV62071491; called by muse, mutect2
- PLCH2 | c.3854G>A p.G1285E | Missense Mutation (SNP) | VAF 46/640 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs528048160, COSV53941447; called by muse, mutect2
- PNLIP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV65041289; called by muse, mutect2
- PNLIPRP1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100724237; called by muse, mutect2
- PODXL | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59868825; called by muse, mutect2, varscan2
- POMZP3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs780049330; called by muse, mutect2
- POTEE | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 52/837 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.404); catalogued as rs754500374; called by muse, mutect2
- POU2F2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.956); catalogued as rs1459954171; called by muse, mutect2
- POU6F2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 52/484 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68867435; called by muse, mutect2, varscan2
- PPFIA2 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.91); catalogued as COSV61054330; called by muse, mutect2
- PRAG1 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs781629031; called by muse, mutect2
- PRAMEF12 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV63215614, COSV63216513; called by muse, mutect2
- PRB3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs748592997; called by muse, mutect2
- PRDM16 | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 83/547 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs540487766, COSV54594526; called by muse, mutect2, varscan2
- PREX2 | c.4250G>A p.G1417E | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55793305; called by muse, mutect2, varscan2
- PRKCQ | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 28/339 reads (8%) | catalogued as rs774410928; called by muse, mutect2
- PROKR2 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 32/434 reads (7%) | catalogued as COSV54087730; called by muse, mutect2
- PROSER1 | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61488490; called by muse, mutect2
- PRR5 | c.869C>T p.P290L (on ENST00000336985 / NM_181333.4; = p.P281L on NM_015366.4) | Missense Mutation (SNP) | VAF 45/482 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1410601340; called by muse, mutect2
- PRRC2A | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 26/431 reads (6%) | catalogued as COSV65685838; called by muse, mutect2
- PRSS37 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63339557; called by muse, varscan2
- PRTN3 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1275750326; called by muse, mutect2
- PRUNE2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.293); catalogued as COSV65028078; called by muse, mutect2
- PSG7 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV68446114; called by muse, mutect2
- PSG7 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 55/568 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs181621391, COSV68444247, COSV68446558; called by muse, mutect2
- PTPRD | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs1428808899; called by muse, mutect2
- PTPRF | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750275015; called by muse, mutect2
- PTPRZ1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 40/333 reads (12%) | catalogued as rs771283585, COSV66436171, COSV66436709; called by muse, mutect2, varscan2
- PWWP3B | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs779990784; called by muse, mutect2, varscan2
- RAPGEF4 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1238555512, COSV51384576; called by muse, mutect2
- RAPGEF5 | c.530G>A p.R177K (on ENST00000401957 / NM_001367602.2; = p.R480K on NM_012294.5) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as rs928560533; called by muse, mutect2, varscan2
- RBFOX3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1217852980; called by muse, mutect2, varscan2
- RFX6 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs762347873; called by muse, mutect2
- RGPD3 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV58744082; called by muse, mutect2
- RHOB | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV55355615, COSV55357131; called by muse, mutect2
- RNASE2 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); catalogued as COSV58941164; called by muse, mutect2
- RNF135 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV60434323; called by muse, mutect2, varscan2
- RTKN2 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1256537620; called by muse, mutect2
- SDR42E1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61094187; called by muse, mutect2
- SEC16B | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as rs1050528043; called by muse, mutect2, varscan2
- SEC63 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 9/168 reads (5%) | catalogued as CM122185, COSV64600342; called by muse, mutect2
- SERTAD2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 39/489 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs201223148; called by muse, mutect2
- SFTPA2 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs778094757; called by muse, mutect2
- SHB | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100891911; called by muse, mutect2
- SLC15A2 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55196465; called by muse, mutect2
- SLC16A11 | c.365C>T p.S122L (on ENST00000308009; = p.S98L on NM_153357.3) | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1331887223, COSV57274425; called by muse, mutect2, varscan2
- SLC22A15 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.131); catalogued as COSV65680300; called by muse, mutect2
- SLC22A23 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66677638; called by muse, mutect2
- SLC22A8 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1001784854, COSV60324957; called by muse, mutect2
- SLC24A3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 33/482 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs769765422, COSV60118640; called by muse, mutect2
- SLC26A2 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1468912886; called by muse, mutect2
- SLC26A4 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749325776, COSV55919858; called by muse, mutect2, varscan2
- SLC26A9 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778478558, COSV61604513; called by muse, mutect2
- SLC6A2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.052); catalogued as rs200894116; called by muse, mutect2
- SLC8A2 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as rs1425415320; called by muse, mutect2
- SLPI | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100619818, COSV58092262; called by muse, mutect2
- SNAPC4 | c.3601C>T p.P1201S | Missense Mutation (SNP) | VAF 34/461 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100046696; called by muse, mutect2
- SNCAIP | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs901682731, COSV54408079; called by muse, mutect2
- SNX24 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV54453130; called by muse, mutect2
- SORCS3 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs990179075; called by muse, mutect2, varscan2
- SORL1 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as rs747369466, COSV52750047; called by muse, mutect2, varscan2
- SPAG17 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60452433; called by muse, mutect2, varscan2
- SPATA31A1 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 48/618 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.05); catalogued as COSV66533340; called by muse, mutect2
- SPEG | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs752042435; called by muse, mutect2
- SPOP | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1412582124, COSV61652966; called by muse, mutect2
- SPSB4 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350088124; called by muse, mutect2
- SPTA1 | c.5161G>A p.D1721N | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.337); catalogued as COSV100934050, COSV100935900; called by muse, mutect2, varscan2
- SPTA1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1354772766; called by muse, mutect2
- SRD5A2 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs768525253; called by muse, mutect2
- ST8SIA3 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 18/181 reads (10%) | PolyPhen benign (0.005); catalogued as COSV60654412; called by muse, mutect2
- STAC2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV61064903; called by muse, mutect2, varscan2
- STK31 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63457158; called by muse, mutect2
- STXBP5 | c.3203C>T p.S1068L (on ENST00000321680 / NM_001127715.2; = p.S1032L on NM_139244.4) | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV51650547; called by muse, mutect2
- SULT1C2 | c.378C>T p.F126= | Splice Region (SNP) | VAF 12/258 reads (5%) | catalogued as COSV52263876; called by muse, mutect2
- SVEP1 | c.7585C>T p.R2529W | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs779073227, COSV52834974; called by muse, mutect2
- SYNPO2 | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs199913740, COSV100204788, COSV100204901; called by muse, mutect2
- SYT10 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57345274; called by muse, mutect2
- SYVN1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 32/457 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs752004047; called by muse, mutect2
- TAF1B | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55157173; called by muse, mutect2
- TAS1R2 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 25/447 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV100946163; called by muse, mutect2
- TBC1D30 | c.2482G>A p.D828N (on ENST00000542120; = p.D665N on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1450658376; called by muse, mutect2, varscan2
- TBC1D5 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs200832725, COSV99511064; called by muse, mutect2
- TBXAS1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778831274, COSV54951060; called by muse, mutect2, varscan2
- TCHHL1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 43/470 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV64284839; called by muse, mutect2
- TCHHL1 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs984285030, COSV64285632; called by muse, mutect2, varscan2
- TENM1 | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.992); catalogued as COSV64430056; called by muse, mutect2, varscan2
- TET2 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54433113; called by muse, mutect2
- TEX52 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs926304579; called by muse, mutect2
- THSD7A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs199747317; called by muse, mutect2, varscan2
- TINAGL1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1370037691; called by muse, mutect2, varscan2
- TLCD3B | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 31/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921852313, COSV99662454; called by muse, mutect2
- TLR4 | c.2061G>A p.W687* (on ENST00000355622 / NM_138554.5; = p.W647* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 18/384 reads (5%) | catalogued as COSV62922427; called by muse, mutect2
- TMC1 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs369890353; ClinVar: uncertain significance; called by muse, mutect2
- TMC5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as rs1217466388; called by muse, mutect2
- TMEM130 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1554397671, COSV59557924; called by muse, mutect2
- TMEM63B | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 26/374 reads (7%) | catalogued as COSV99440842; called by muse, mutect2
- TMEM8B | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs760684061, COSV100941688; called by muse, mutect2
- TNFRSF11A | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs951428243; called by muse, mutect2
- TNNT1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752992299; ClinVar: uncertain significance; called by muse, mutect2
- TNR | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1466807767, COSV54887922, COSV99056728; called by muse, mutect2
- TNS4 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs900157045; called by muse, mutect2
- TRANK1 | c.6739G>A p.E2247K | Missense Mutation (SNP) | VAF 38/405 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100083056, COSV57166263, COSV57166300; called by muse, mutect2
- TRBV29-1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.772); catalogued as rs1435474511; called by muse, mutect2, varscan2
- TRIB2 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1357934399, COSV99331323; called by muse, mutect2
- TSPAN2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.041); catalogued as COSV65690485; called by muse, mutect2
- TTC23 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs746739734, COSV50441974; called by muse, mutect2
- TTC6 | c.1246G>A p.E416K (on ENST00000267368; = p.E1782K on NM_001310135.3) | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs865814638, COSV99942044; called by muse, mutect2
- TTN | c.80257G>A p.D26753N (on ENST00000591111; = p.D19329N on NM_003319.4) | Missense Mutation (SNP) | VAF 34/368 reads (9%) | PolyPhen probably damaging (0.998); catalogued as COSV60244643; called by muse, mutect2
- TTN | c.54017G>A p.G18006E (on ENST00000591111; = p.G10582E on NM_003319.4) | Missense Mutation (SNP) | VAF 36/389 reads (9%) | PolyPhen probably damaging (1); catalogued as rs1559611400, COSV60214642; called by muse, mutect2
- TTN | c.42799C>T p.R14267C (on ENST00000591111; = p.R6843C on NM_003319.4) | Missense Mutation (SNP) | VAF 31/299 reads (10%) | PolyPhen probably damaging (0.998); catalogued as rs767724702, COSV100587926, COSV59902174; called by muse, mutect2
- TTN | c.27524C>T p.P9175L (on ENST00000591111; = p.P8248L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/216 reads (6%) | PolyPhen probably damaging (0.999); catalogued as rs1175811768, COSV100605484, COSV60142502; called by muse, mutect2
- TTN | c.23398G>A p.E7800K (on ENST00000591111; = p.E6873K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/526 reads (6%) | PolyPhen probably damaging (0.994); catalogued as COSV60211737; called by muse, mutect2
- TYR | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as CM091273, COSV99635863; called by muse, mutect2
- TYR | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.045); catalogued as rs896650424, COSV54483223, COSV99635242; called by muse, mutect2, varscan2
- UBD | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 47/540 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs779055798; called by muse, mutect2
- UBQLN3 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs1165321366, COSV100293824, COSV61164176; called by muse, mutect2
- UBQLN3 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1216448012; called by muse, mutect2
- UBXN2B | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68308774; called by muse, mutect2
- UNC45B | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 37/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568137119; called by muse, mutect2
- UNC5D | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 33/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54809032; called by muse, mutect2
- UNC79 | c.2312C>T p.P771L (on ENST00000393151 / NM_001346218.2; = p.P594L on NM_020818.5) | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs751135621, COSV99829212; called by muse, mutect2
- UQCRHL | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.035); catalogued as rs764654397, COSV72331662; called by muse, mutect2
- URGCP-MRPS24 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT tolerated, low confidence (0.27); catalogued as rs1287811024; called by muse, mutect2, varscan2
- USH2A | c.13598C>T p.S4533L | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56374130; called by muse, mutect2, varscan2
- USH2A | c.6631G>A p.G2211S | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100236183, COSV100242252; called by muse, mutect2, varscan2
- UTP25 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 37/458 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV71965733; called by muse, mutect2
- VIPR2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV51113751; called by muse, mutect2, varscan2
- VRK3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100371197; called by muse, mutect2
- VWA3B | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV68241779; called by muse, mutect2, varscan2
- WWP2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs776475086; called by muse, mutect2, varscan2
- XDH | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1442917442, COSV65148213; called by muse, mutect2
- XKR3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100509134; called by muse, mutect2
- ZCCHC2 | c.1631A>G p.K544R | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV54038323; called by muse, mutect2
- ZFHX4 | c.7391C>T p.S2464L | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV50907517; called by muse, mutect2
- ZGLP1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67059658; called by muse, mutect2, varscan2
- ZIM3 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 19/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54142043; called by muse, mutect2
- ZNF22 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379389713; called by muse, mutect2
- ZNF383 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV61940008; called by muse, mutect2
- ZNF514 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751035147; called by muse, mutect2
- ZNF90 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV69003656; called by muse, mutect2
- ZNF91 | c.3097C>T p.R1033* | Nonsense Mutation (SNP) | VAF 25/241 reads (10%) | catalogued as rs759467410; called by muse, mutect2, varscan2
- ZNF99 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV101233816; called by muse, mutect2
- A1CF | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ABCA4 | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA8 | c.2525C>T p.T842I | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA9 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2
- ABCB4 | c.2784G>A p.R928= | Splice Region (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- ABHD10 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- ABLIM3 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- AC011462.1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- AC126283.2 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACSF2 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ACVR2B | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2
- ADAM19 | c.2857G>A p.V953M | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- ADAM8 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS7 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 23/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADGRB3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2
- ADGRG4 | c.6838C>T p.Q2280* | Nonsense Mutation (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- AHDC1 | c.1914G>A p.W638* | Nonsense Mutation (SNP) | VAF 51/446 reads (11%) | called by muse, mutect2, varscan2
- AHDC1 | c.1913G>A p.W638* | Nonsense Mutation (SNP) | VAF 52/448 reads (12%) | called by muse, mutect2, varscan2
- AKAP4 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AKAP6 | c.6491C>T p.S2164F | Missense Mutation (SNP) | VAF 24/411 reads (6%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.019); called by muse, mutect2
- AL592490.1 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 23/445 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- ALDH3A1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 19/307 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- ALG6 | c.1214T>A p.F405Y | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALS2CL | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- AMIGO3 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- AMPD2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 34/519 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2
- ANKRD18A | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD33 | c.86G>A p.G29E (on ENST00000340970 / NM_001304459.2; = p.G164E on NM_182608.4) | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- ANO10 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.059); called by muse, mutect2
- APBA3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2
- APOB | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); called by muse, mutect2
- ARHGAP20 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 31/365 reads (8%) | called by muse, mutect2
- ARHGAP32 | c.4897C>T p.H1633Y (on ENST00000310343 / NM_001378025.1; = p.H1284Y on NM_014715.4) | Missense Mutation (SNP) | VAF 38/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ASNS | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.3796G>A p.A1266T | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASXL3 | c.6656C>T p.A2219V | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD3A | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ATG2A | c.3157C>T p.H1053Y | Missense Mutation (SNP) | VAF 35/427 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.062); called by muse, mutect2
- ATP8B4 | c.3433G>A p.G1145R | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ATP9B | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- B4GALNT2 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- B4GALNT2 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); called by muse, mutect2
- B4GALNT4 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 33/468 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2
- BCL9 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 61/452 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- BMP6 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRD1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BRICD5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by muse, mutect2
- BRIP1 | c.2494T>A p.C832S | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- BSN | c.6689C>T p.S2230F | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- BSN | c.8293C>T p.P2765S | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTBD8 | c.4049G>A p.W1350* (on ENST00000636805 / NM_001376131.1; = p.W837* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- C10orf71 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 33/467 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.11); called by muse, mutect2
- C8B | c.1269G>T p.L423F | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CACNA1B | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D3 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- CASP5 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC106 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC141 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.209); called by muse, mutect2
- CCDC168 | c.5558G>A p.G1853E | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.292); called by muse, mutect2
- CCDC169 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- CCDC54 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2
- CCDC66 | c.335C>T p.S112L (on ENST00000394672 / NM_001353147.1; = p.S78L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC83 | c.805C>T p.L269F (on ENST00000342404 / NM_001286159.2; = p.L300F on NM_173556.5) | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CCL3L3 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCR3 | c.946T>C p.F316L | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2
- CD1E | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 82/475 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CD200 | c.599C>T p.P200L (on ENST00000473539 / NM_001004196.3; = p.P175L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/423 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2
- CD8B | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- CDK12 | c.3938C>T p.P1313L (on ENST00000447079 / NM_016507.4; = p.P1304L on NM_015083.3) | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CENPF | c.8996C>A p.P2999Q | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP112 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CEP135 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP89 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- CFAP251 | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- CFAP54 | c.7804G>A p.E2602K | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.097); called by muse, mutect2
- CFHR5 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2
- CHD6 | c.3256A>G p.N1086D | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2
- CHL1 | c.3403G>A p.E1135K (on ENST00000397491 / NM_001253387.1; = p.E1151K on NM_006614.4) | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CKAP5 | c.5794C>T p.P1932S (on ENST00000529230 / NM_001008938.4; = p.P1872S on NM_014756.3) | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- CLCA2 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CLEC17A | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- CLSTN3 | c.2569G>A p.G857S | Missense Mutation (SNP) | VAF 45/515 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2
- CNIH1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- COL1A1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL21A1 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL22A1 | c.93T>C p.G31= | Splice Region (SNP) | VAF 31/198 reads (16%) | called by muse, mutect2, varscan2
- COL28A1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL3A1 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL4A5 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A6 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- COL4A6 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL9A1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2
- COPS8 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- CPEB1 | c.632C>T p.P211L (on ENST00000617958; = p.P151L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.122); called by muse, mutect2
- CPED1 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CRB2 | c.3258G>A p.W1086* | Nonsense Mutation (SNP) | VAF 42/526 reads (8%) | called by muse, mutect2
- CYBB | c.534_548del p.G179_T183del | In Frame Del (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- CYP19A1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2
- DCDC1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2
- DDX17 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEFB110 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2
- DENND5B | c.2682G>A p.K894= | Splice Region (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- DIO2 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DIPK1C | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- DLEC1 | c.1061T>G p.I354R | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2
- DLGAP4 | c.2621C>T p.P874L (on ENST00000339266 / NM_001365621.1; = p.P871L on NM_014902.6) | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMRT3 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH10 | c.4529G>A p.G1510E (on ENST00000409039; = p.G1449E on NM_207437.3) | Missense Mutation (SNP) | VAF 31/507 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DNAH11 | c.7544G>A p.G2515E | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH3 | c.8693C>T p.A2898V | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- DNAH3 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAH3 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2
- DNAI4 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAJC6 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 39/437 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- DOP1B | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- DPP10 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- DPP4 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPY19L1 | c.2026T>G p.*676Gext*32 | Nonstop Mutation (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- DPYD | c.1703G>A p.W568* | Nonsense Mutation (SNP) | VAF 34/305 reads (11%) | called by muse, mutect2, varscan2
- DSP | c.5209G>T p.G1737* | Nonsense Mutation (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- DST | c.8186C>T p.S2729L | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP6 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DYSF | c.724A>T p.K242* | Nonsense Mutation (SNP) | VAF 20/357 reads (6%) | called by muse, mutect2
- EDA2R | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EFHC1 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- EHHADH | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- ELAPOR1 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ELOA2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- EMID1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- EML6 | c.3352G>A p.V1118I | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2
- ENPP3 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENTHD1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPB41L4A | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- EPG5 | c.3030G>T p.L1010F | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2
- EPHB2 | c.2934G>A p.M978I (on ENST00000400191 / NM_001309193.2; = p.M979I on NM_004442.7) | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ESYT1 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- EVPL | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- EXPH5 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- EYS | c.5521G>A p.E1841K | Missense Mutation (SNP) | VAF 35/405 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); called by muse, mutect2
- F13A1 | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 25/359 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- FAM124A | c.280C>T p.P94S (on ENST00000322475 / NM_001242312.2; = p.P130S on NM_145019.4) | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.083); called by muse, mutect2
- FAM126A | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FAM160A1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.076); called by muse, mutect2
- FAM170B | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 41/460 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- FAM217A | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- FAM71F1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- FANCD2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.859); called by muse, mutect2
- FAT4 | c.5452G>A p.D1818N | Missense Mutation (SNP) | VAF 33/436 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBH1 | c.869T>G p.V290G (on ENST00000362091 / NM_178150.3; = p.V341G on NM_032807.4) | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- FBN2 | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.182); called by muse, mutect2
- FBXO30 | c.1552A>T p.M518L | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2
- FLG | c.2621C>T p.T874I | Missense Mutation (SNP) | VAF 90/654 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FLG2 | c.6428G>C p.R2143T | Missense Mutation (SNP) | VAF 82/491 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FLG2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- FLNC | c.8011G>A p.G2671S | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXE1 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 37/536 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2
- FOXJ3 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMD3 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 42/417 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FSIP2 | c.16342G>A p.D5448N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.099); called by muse, mutect2
- FZD3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALK2 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GCN1 | c.3376C>T p.L1126F | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.397); called by muse, mutect2
- GJC1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); called by muse, mutect2
- GLT8D2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2
- GRAMD1C | c.1837A>G p.I613V | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- GRAMD4 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.705); called by muse, mutect2
- GRIA1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2
- GRIP2 | c.410C>T p.P137L (on ENST00000619221; = p.P40L on NM_001080423.4) | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- GRK1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRM6 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- GSG1 | c.51G>A p.M17I (on ENST00000651961 / NM_001080555.4; = p.M4I on NM_031289.5) | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- HDGFL1 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 43/612 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- HECW1 | c.3691C>T p.L1231F | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HEG1 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEG1 | c.1642T>A p.S548T | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- HERC1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- HHIP | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- HMGXB4 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- HORMAD2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 25/375 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2
- HOXD3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2
- HTR6 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 30/302 reads (10%) | called by muse, mutect2
- HTT | c.5354A>T p.H1785L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGHA1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 39/898 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- INPP5J | c.2306C>T p.S769F (on ENST00000331075 / NM_001284285.2; = p.S401F on NM_001002837.2) | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KANSL1 | c.743T>A p.L248* | Nonsense Mutation (SNP) | VAF 75/524 reads (14%) | called by muse, mutect2, varscan2
- KCNH5 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 21/458 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 35/431 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2
- KCNJ5 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNK5 | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 51/501 reads (10%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2428G>A p.D810N (on ENST00000286628 / NM_001161352.2; = p.D752N on NM_002247.4) | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- KCNT1 | c.2203C>T p.P735S (on ENST00000488444; = p.P754S on NM_020822.3) | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- KCTD3 | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 29/417 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- KDM2A | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- KIF1A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF26A | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 36/485 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- KIF6 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.242); called by muse, mutect2
- KIR2DL3 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2
- KLF17 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KLHL1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- KLHL14 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2
- KMT2C | c.10196A>G p.E3399G | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRT23 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KRT5 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2
- L3MBTL1 | c.1507C>T p.P503S (on ENST00000418998 / NM_001377303.1; = p.P413S on NM_015478.7) | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LACTB2 | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); called by muse, mutect2
- LAMC2 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2
- LAMC2 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.272); called by muse, mutect2
- LAMC2 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- LCN1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.262); called by muse, mutect2
- LCOR | c.4412C>T p.S1471F | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.22); called by muse, mutect2
- LCORL | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- LGALS16 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- LILRB4 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 35/522 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2
- LIPE | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 62/634 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LMLN2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LOXHD1 | c.5131G>A p.E1711K (on ENST00000642948; = p.E600K on NM_001145472.3) | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LOXL4 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPCAT2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- LRP1B | c.5680C>T p.L1894F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRC3C | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC53 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LRRC74A | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- LRRC75B | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2
- LY6G6F-LY6G6D | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 54/689 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MAB21L3 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MAGEA6 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAN2A2 | c.2456A>T p.D819V | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2
- MAPK4 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 43/444 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.806); called by muse, mutect2
- MARCHF4 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- MAST1 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST3 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- MCM10 | c.587C>T p.S196L (on ENST00000484800 / NM_182751.3; = p.S195L on NM_018518.5) | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MEI4 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2
- MGAM2 | c.6955C>T p.P2319S | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated, low confidence (0.17); called by muse, mutect2, varscan2
- MICU2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- MLNR | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.045); called by muse, mutect2
- MPP7 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.77); called by muse, mutect2
- MROH6 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.147); called by muse, mutect2
- MTMR14 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- MUC16 | c.31860T>G p.S10620R | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.093); called by muse, mutect2
- MUC16 | c.31859G>A p.S10620N | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2
- MUC16 | c.12167G>A p.R4056K | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); called by muse, mutect2
- MUC16 | c.6040C>T p.P2014S | Missense Mutation (SNP) | VAF 27/353 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- MYH7B | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MYH8 | c.3737G>A p.G1246E | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- MYLK3 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- MYO18B | c.6572C>T p.P2191L | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- MYO1G | c.2658C>A p.N886K | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- MYO7A | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- MYO7A | c.6019C>T p.P2007S | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- NCAPG2 | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- NFKB1 | c.1219C>T p.P407S (on ENST00000394820 / NM_001382627.1; = p.P408S on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- NHS | c.2679G>A p.W893* | Nonsense Mutation (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- NLRC4 | c.1846T>A p.F616I | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- NLRP1 | c.3916G>A p.E1306K (on ENST00000572272 / NM_033004.4; = p.E1262K on NM_014922.5) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS1AP | c.345G>A p.R115= | Splice Region (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- NPAP1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.298); called by muse, mutect2
- NPIPB7 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPR1 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 64/438 reads (15%) | called by muse, mutect2, varscan2
- NPY1R | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.721); called by muse, mutect2
- NR1D2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- NRG3 | c.1595G>A p.R532K (on ENST00000404547 / NM_001370084.1; = p.R311K on NM_001165973.1) | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NSD3 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 27/459 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- NTN3 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2
- NUP210L | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NXPE2 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.285); called by muse, mutect2
- OPTC | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 58/375 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR10G6 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.554); called by muse, mutect2
- OR10H5 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR13C2 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- OR1B1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2
- OR4C5 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- OR4K3 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 25/717 reads (3%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- OR51E2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR51I1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5H15 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- OR5V1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- OR6K2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- OR9H1P | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OSGEP | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- OVCH2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- OVOL2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 24/403 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.34); called by muse, mutect2
- P3H2 | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- PAIP2B | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PARD3B | c.3319G>A p.E1107K (on ENST00000406610 / NM_001302769.2; = p.E1038K on NM_057177.7) | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.254); called by muse, mutect2
- PARP10 | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); called by muse, mutect2
- PASK | c.986C>G p.A329G | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.171); called by muse, mutect2
- PCDH10 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDH15 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH19 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB1 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.6288G>A p.M2096I | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.5860G>A p.D1954N | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE5A | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2
631 further variants in this file (153 protein-altering or splice-affecting, 426 silent, 52 other) are not listed here.
